Surgical pathology report (de-identified scan), TCGA case TCGA-D6-6826, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-6826-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 1

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.

Patient: XXX

PESEL: XXX

Age:

Gender: M

Material: **Lesion resection – larynx**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Tumour of the larynx**

Examination performed on:

Macroscopic description:

Surgical specimen sized 7.5 x 5.2 x 3.3 cm containing the larynx, hyoid bone and a 1.5 cm piece of the trachea. Tumour sized 2 x 1.7 x 1.1 cm in the subglottal region infiltrating into the glottis on the left side, the thyroid cartilage and the infrahyoid region.

Microscopic description:

Carcinoma planoepitheliale keratodes invasivum G2.

The tumour infiltrates into glottis, anterior commissure, the thyroid cartilage and the infrahyoid region.

Neoplastic proliferation found in the front incision line, showing high degree of epithelium paraepidermoidale dysplasia. The other incision lines free of neoplastic proliferation.

Histopathological Diagnosis:

Carcinoma planoepitheliale keratodes invasivum laryngis. Invasive squamous keratinized carcinoma of the larynx.

G2, pT4a, pN2b.

Compliance validated

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file e2e9286c-ca9f-4e79-98ea-29e912cd09e6 (TCGA-D6-6826.D01AD619-BC9B-4F8E-BEB5-93C08539874A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).